Surgical pathology report (de-identified scan), TCGA case TCGA-F4-6704, project TCGA-COAD (Colon Adenocarcinoma), tissue source site Asterand, specimen TCGA-F4-6704-01A (Primary Tumor).

[page 1 of 2]
Formatted Path Report

LARGE INTESTINE TISSUE
CHECKLIST

Specimen type: Colectomy
Specimen size: Not specified
Tumor site: Sigmoid colon
Tumor size: 5.2 x 2.2 cm
Tumor features: Infiltrative,
Ulcerated
Histologic type: Mucinous
adenocarcinoma
Histologic grade: Poorly
differentiated
Tumor extent: Subserosa
Lymph nodes: 13/18 positive for
metastasis (Pericolic 13/18)
Margins: Uninvolved
Evidence of neo-adjuvant treatment:
Not specified
Additional pathologic findings: Not
specified
Comments: None

[page 2 of 2]
Date of Procurement

Source: NCI Genomic Data Commons file c3091a8d-5ce2-4c5f-9a48-23bb4a1ae7f5 (TCGA-F4-6704.FDE549EE-A203-4D65-8F24-9F450E6F3857.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).